Somatic mutation profile of tumor specimen SM-JU352 (aliquot 7316UP-181) from CPTAC case C234192, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU352: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fd18ea9-7fac-4e27-97ea-b43f48db0dec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105286 (Blood Derived Normal), aliquot 7316UP-386-1105286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12a3423b-5964-472f-953b-5cd02c266aee

The open-access MAF lists 107 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 22, Intron 8, Nonsense Mutation 5, Frame Shift Del 4, Splice Region 3, 3'Flank 3, Frame Shift Ins 2, 3'UTR 2, 5'UTR 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B10 | c.742-7C>T | Splice Region (SNP) | VAF 71/353 reads (20%) | catalogued as rs766204329; called by muse, mutect2, varscan2
- AL592490.1 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775154689; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, mutect2, varscan2
- DSCAML1 | c.5677G>A p.E1893K (on ENST00000321322; = p.E1833K on NM_020693.4) | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208211363; called by muse, mutect2, varscan2
- EBPL | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as rs200901347, COSV54431481; called by mutect2, varscan2
- FZD9 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs547599913; called by muse, mutect2
- GK2 | c.117C>A p.H39Q | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV62627486; called by muse, mutect2, varscan2
- GPATCH8 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59195790, COSV59196909; called by muse, mutect2, varscan2
- IGHA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs753985358; called by muse, mutect2, varscan2
- IGHG2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762234471; called by muse, mutect2, varscan2
- ITGAM | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.18); catalogued as rs755777607, COSV54933096; called by muse, mutect2, varscan2
- KCNE1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs142511345, CM097709; ClinVar: not provided / likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- LCN10 | c.536C>T p.A179V (on ENST00000474369 / NM_001368089.1; = p.A192V on NM_001001712.3) | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as rs751195542; called by muse, mutect2, varscan2
- MAPK15 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 59/176 reads (34%) | catalogued as rs782012920; called by muse, mutect2, varscan2
- METTL25 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759475773, COSV99942386; called by muse, mutect2, varscan2
- MUC16 | c.12422G>T p.G4141V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1018086393; called by muse, mutect2, varscan2
- MYBPC3 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs199893357, COSV57031555; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- NLRP5 | c.62+1G>A p.X21_splice | Splice Site (SNP) | VAF 36/163 reads (22%) | catalogued as rs199475763; ClinVar: not provided; called by muse, mutect2, varscan2
- OR14A2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs779547225; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, varscan2
- PDE10A | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.857); catalogued as COSV63050056; called by muse, varscan2
- PPARGC1B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs753410582; called by muse, mutect2, varscan2
- PTEN | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64307058; called by muse, mutect2, varscan2
- RDH10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 137/403 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs190882720, COSV53582156; called by muse, mutect2, varscan2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1026402297, COSV55673390, COSV99693589; called by muse, mutect2, varscan2
- SSUH2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs147081374; called by muse, mutect2, varscan2
- STK32C | c.1119C>T p.N373= | Splice Region (SNP) | VAF 46/81 reads (57%) | catalogued as rs745931599; called by muse, mutect2, varscan2
- TIMD4 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 90/287 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779272298; called by muse, mutect2, varscan2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, mutect2, varscan2
- WWC2 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs1237914404; called by muse, mutect2, varscan2
- ZBTB39 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 78/247 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55630225; called by muse, mutect2, varscan2
- ZNF578 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 24/314 reads (8%) | catalogued as rs767983794, COSV69737570; called by muse, mutect2
- ZNF804A | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373088099; called by muse, varscan2
- ZP2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs558301595, COSV54814788; called by muse, mutect2, varscan2
- ADAMTS16 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADRA2C | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APC | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARFGEF3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAT1 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPN2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH12 | c.3374G>T p.S1125I (on ENST00000351747; = p.S1148I on NM_001366028.2) | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DST | c.21967dup p.S7323Ffs*53 (on ENST00000361203 / NM_001374722.1; = p.S4996Ffs*22 on NM_015548.5) | Frame Shift Ins (INS) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- FASLG | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GNAQ | c.397_400del p.K133Vfs*34 | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | called by mutect2, pindel, varscan2
- GNL2 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IWS1 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- KCNT2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KHSRP | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MANSC1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR1B1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.679); called by muse, mutect2
- OTOG | c.6338C>T p.S2113L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PCYT1A | c.123dup p.R42Tfs*8 | Frame Shift Ins (INS) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- RLF | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF17 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPL5 | c.23_25delinsTT p.K8Ifs*11 | Frame Shift Del (DEL) | VAF 49/175 reads (28%) | called by pindel, varscan2*
- SAMM50 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC6A17 | c.299del p.V100Gfs*7 | Frame Shift Del (DEL) | VAF 34/110 reads (31%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- TMEM132C | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTK | c.2310T>C p.C770= | Splice Region (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- UBN1 | c.1384_1385del p.K462Vfs*33 | Frame Shift Del (DEL) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- UNC5A | c.2162G>A p.S721N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); called by mutect2, varscan2
- UNC80 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 60/242 reads (25%) | called by muse, mutect2, varscan2
- ZFPL1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- ZNF185 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZNF200 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ZNF765 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ABCA7 | c.2325C>T p.C775= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs771423478; called by muse, mutect2, varscan2
- ADAMTS7 | c.2340G>T p.T780= | Silent (SNP) | VAF 142/425 reads (33%) | catalogued as COSV101182994; called by muse, mutect2, varscan2
- ANKRD24 | c.1611C>T p.T537= | Silent (SNP) | VAF 102/345 reads (30%) | called by muse, mutect2, varscan2
- CPNE9 | c.168C>T p.T56= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as rs1272915216; called by muse, mutect2
- DLGAP3 | c.2166C>T p.A722= | Silent (SNP) | VAF 84/237 reads (35%) | catalogued as rs764770295; called by muse, mutect2, varscan2
- FAM172A | c.178C>T p.L60= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV67936404; called by muse, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 61/208 reads (29%) | catalogued as COSV100172159; called by muse, mutect2, varscan2
- KANK3 | c.1839G>A p.A613= | Silent (SNP) | VAF 123/495 reads (25%) | catalogued as rs368061289, COSV58360783; called by muse, mutect2, varscan2
- KLK12 | c.564C>T p.G188= | Silent (SNP) | VAF 99/447 reads (22%) | catalogued as rs145723658; called by muse, mutect2, varscan2
- LRIT3 | c.1215C>G p.P405= | Silent (SNP) | VAF 81/230 reads (35%) | called by muse, mutect2, varscan2
- MTFR1 | c.576G>A p.P192= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs770323230; called by muse, mutect2, varscan2
- MYH6 | c.4083C>T p.R1361= | Silent (SNP) | VAF 50/250 reads (20%) | catalogued as rs568275249, COSV62449434; called by muse, mutect2, varscan2
- OPLAH | c.864G>A p.S288= | Silent (SNP) | VAF 55/176 reads (31%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2, varscan2
- OR8J3 | c.838T>C p.L280= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- SCN10A | c.2973G>A p.P991= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs201397469; ClinVar: likely benign; called by muse, mutect2
- SIPA1L3 | c.3849C>T p.S1283= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs761002860, COSV55924999; called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 59/222 reads (27%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SON | c.2874A>C p.L958= | Silent (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- TRMT6 | c.567C>T p.A189= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs759809544; called by muse, mutect2, varscan2
- TTC6 | c.2556T>C p.D852= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as rs1363199747; called by muse, mutect2, varscan2
- USH2A | c.3735A>G p.R1245= | Silent (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 87/371 reads (23%) | called by muse, mutect2, varscan2
- ABCC5 | c.3694+237G>A | Intron (SNP) | VAF 83/250 reads (33%) | catalogued as rs760020200; called by muse, mutect2, varscan2
- AIRE | c.*14G>A | 3'UTR (SNP) | VAF 131/421 reads (31%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1552+95G>A | Intron (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- CD37 | c.343-174G>A | Intron (SNP) | VAF 41/128 reads (32%) | catalogued as rs1210480550; called by muse, mutect2, varscan2
- COBLL1 | c.344+70C>T | Intron (SNP) | VAF 22/63 reads (35%) | catalogued as rs754831585; called by muse, mutect2, varscan2
- CYP39A1 | c.*10G>C | 3'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as rs1351642807; called by muse, mutect2, varscan2
- LFNG | chr7:2528892 G>A | 3'Flank (SNP) | VAF 32/109 reads (29%) | catalogued as rs562235848, COSV56069254; called by muse, mutect2, varscan2
- LINC00479 | n.492C>T | RNA (SNP) | VAF 59/173 reads (34%) | called by muse, mutect2, varscan2
- MICAL1 | c.2305-47G>C | Intron (SNP) | VAF 52/187 reads (28%) | called by muse, mutect2
- RNU7-115P | chr17:64821949 C>T | 3'Flank (SNP) | VAF 142/417 reads (34%) | catalogued as rs755561023; called by muse, varscan2
- RPL27A | c.-1C>G | 5'UTR (SNP) | VAF 28/99 reads (28%) | catalogued as rs754250435; called by muse, mutect2, varscan2
- RPS21 | c.114+83G>A | Intron (SNP) | VAF 26/95 reads (27%) | catalogued as rs1422411816; called by muse, mutect2, varscan2
- SPAG6 | c.-32G>C | 5'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- SPINK5 | c.475-411T>C | Intron (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- WDR49 | c.487-6642A>C | Intron (SNP) | VAF 30/100 reads (30%) | catalogued as COSV100393346; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836439 C>T | 3'Flank (SNP) | VAF 34/139 reads (24%) | catalogued as rs759235923; called by muse, mutect2, varscan2
